National Lung Screening Trial (NLST) participant 216749 — screening results and CT findings
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 60 years; Gender: female; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through an American College of Radiology Imaging Network (ACRIN) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 0): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer. Exam quality: limited CT, but interpretable (motion artifact); technique as recorded on the form: 120 kVp, 70 mA, display field of view 24 cm, reconstruction filter GE Bone / GE Standard.
- T1 (day 341): Negative screen, minor abnormalities not suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 70 mA, display field of view 27 cm, reconstruction filter GE Bone / GE Standard.
- T2 (day 700): Positive, other. Isolation read, before comparison with prior images: negative screen, significant abnormalities not suspicious for lung cancer. Exam quality: limited CT, but interpretable (motion artifact); technique as recorded on the form: 120 kVp, 70 mA, display field of view 30 cm, reconstruction filter GE Bone / GE Standard.

Abnormalities recorded by the reading radiologist on the CT screens (17 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right upper lobe; longest diameter 4 mm, longest perpendicular diameter 3 mm; margins poorly defined; predominant attenuation ground glass; greatest diameter on CT slice 44.
- T0 abnormality 2: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T0 abnormality 3: Pleural thickening or effusion.
- T0 abnormality 4: Significant cardiovascular abnormality.
- T0 abnormality 5: Other potentially significant abnormality above the diaphragm.
- T0 abnormality 6: Other potentially significant abnormality above the diaphragm.
- T1 abnormality 1: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T1 abnormality 2: Other minor abnormality noted.
- T1 abnormality 3: Pleural thickening or effusion.
- T1 abnormality 4: Other minor abnormality noted.
- T2 abnormality 1: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T2 abnormality 2: Other potentially significant abnormality above the diaphragm; pre-existing on earlier images (earliest visible day 0); interval change warrants further investigation.
- T2 abnormality 3: Other minor abnormality noted.
- T2 abnormality 4: Other minor abnormality noted.
- T2 abnormality 5: Other minor abnormality noted.
- T2 abnormality 6: Pleural thickening or effusion.
- T2 abnormality 7: Other potentially significant abnormality above the diaphragm; identified only on comparison with prior images.

Follow-up
No confirmed lung cancer during the trial; Last known free of lung cancer: day 2,648.
